Somatic mutation profile of tumor specimen 0DOBTB from CCDI case PBCBYG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Angiomatoid fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 7.8 years (2,834 days).
Specimen 0DOBTB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6165cd4f-f28b-4f01-83c1-58a4117be00c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOBSP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dacff4ff-9328-42ce-90bd-c6e9e437e516

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 2, Frame Shift Del 2, Nonsense Mutation 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRBA | c.1376T>A p.L459* | Nonsense Mutation (SNP) | VAF 130/518 reads (25%) | called by muse, mutect2, varscan2
- NRP1 | c.862del p.S288Lfs*21 | Frame Shift Del (DEL) | VAF 178/722 reads (25%) | called by mutect2, pindel, varscan2
- PLCB1 | c.1044G>A p.M348I | Missense Mutation (SNP) | VAF 26/958 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.18); called by muse, mutect2
- POU5F1B | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 32/902 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- TESK1 | c.1067_1074del p.R356Pfs*107 | Frame Shift Del (DEL) | VAF 139/685 reads (20%) | called by mutect2, pindel, varscan2
- CDHR2 | c.2304C>T p.Y768= | Silent (SNP) | VAF 219/874 reads (25%) | catalogued as rs565179867, COSV56142447, COSV99991052; called by muse, mutect2, varscan2
- CNOT4 | c.786T>C p.N262= | Silent (SNP) | VAF 143/602 reads (24%) | called by muse, varscan2
- FAM83A | c.774-4852C>A | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- KRTAP13-2 | c.*52C>T | 3'UTR (SNP) | VAF 52/165 reads (32%) | called by muse, mutect2, varscan2
